Somatic mutation profile of tumor specimen TCGA-EM-A3AO-01A (aliquot TCGA-EM-A3AO-01A-11D-A202-08) from TCGA case TCGA-EM-A3AO, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 61.2 years (22,347 days).
Specimen TCGA-EM-A3AO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 003a46d6-aba2-4156-ada2-27e5f861c9d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3AO-10A (Blood Derived Normal), aliquot TCGA-EM-A3AO-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/534f7bc1-2c78-43ca-b92f-82b20b63f627

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRRN4 | c.1451G>A p.G484D | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV66645947; called by muse, mutect2, varscan2
- MYH6 | c.2018G>A p.R673H | Missense Mutation (SNP) | VAF 70/223 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1023327699, COSV62449506; called by muse, mutect2, varscan2
- NEK8 | c.1952A>G p.D651G | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV52046401; called by muse, mutect2, varscan2
- PDE5A | c.1433C>G p.T478S | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV53350086; called by muse, mutect2, varscan2
- TG | c.418T>G p.C140G | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55083761; called by muse, mutect2, varscan2
- ITGAL | c.856-2del p.X286_splice | Splice Site (DEL) | VAF 71/225 reads (32%) | called by mutect2, pindel, varscan2
- KCNG2 | c.1185G>A p.L395= | Silent (SNP) | VAF 7/94 reads (7%) | catalogued as COSV60268804; called by muse, mutect2
- TNKS1BP1 | c.4242C>T p.Y1414= | Silent (SNP) | VAF 142/452 reads (31%) | catalogued as COSV64101654; called by muse, mutect2, varscan2
